CCDI case PBCNEL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Lip.
https://portal.gdc.cancer.gov/cases/486a53c1-ccd1-4557-b0c6-ce63d9326838

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Commissure of lip; Age at diagnosis: 2.0 years (726 days).

Biospecimens (3 samples)
- Sample 0DWLYO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWM07: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWM1B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
